TARGET case TARGET-30-PASNML — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Heart, mediastinum, and pleura. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2d79e5c4-ff25-5666-9faa-1097b3a6b7a4

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Age at index: 0 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C38.3; Tissue or organ of origin: Mediastinum, NOS; Classification of tumor: primary; Age at diagnosis: 0.0 years (8 days); Year of diagnosis: 2009; Days to last follow up: 3,396 days (9.3 years); Cog neuroblastoma risk group: Low Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4S; Mitosis karyorrhexis index: Intermediate.
   Pathology details: Percent tumor nuclei: 90.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 3,396 days (9.3 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,396; Year of follow up: 2018.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PASNML-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PASNML-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 3396
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.28
- Histology: Favorable
